Somatic mutation profile of tumor specimen 0DZRYH from CCDI case PBCUIY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DZRYH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7195b35-a39b-404b-8cb5-cefadccd4744.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZRZ2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3daa372-c806-4e96-9c80-42f9d93ed5d3

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 1, Frame Shift Ins 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM7 | c.1919A>G p.N640S | Missense Mutation (SNP) | VAF 26/610 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1156734297; called by muse, mutect2
- ATG16L1 | c.1429C>T p.R477* (on ENST00000392017 / NM_030803.7; = p.R458* on NM_017974.4) | Nonsense Mutation (SNP) | VAF 64/924 reads (7%) | catalogued as COSV61464147, COSV61468342; called by muse, mutect2
- AUP1 | c.1129A>C p.K377Q | Missense Mutation (SNP) | VAF 21/783 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV57818019; called by muse, mutect2
- DUSP3 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 172/443 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749795564, COSV56825098; called by muse, mutect2, varscan2
- RBP3 | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 115/271 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs527458754; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATAD1 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 37/1071 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); called by muse, mutect2
- GPX5 | c.405dup p.E136* | Frame Shift Ins (INS) | VAF 87/617 reads (14%) | called by mutect2, varscan2
- LILRB4 | c.37C>T p.L13= | Splice Region (SNP) | VAF 28/524 reads (5%) | called by muse, mutect2
- MAK | c.1343C>G p.S448C | Missense Mutation (SNP) | VAF 28/808 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- PPFIBP1 | c.1763G>A p.G588D (on ENST00000318304 / NM_177444.3; = p.G582D on NM_003622.4) | Missense Mutation (SNP) | VAF 39/809 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITPRIP | c.1146G>T p.L382= | Silent (SNP) | VAF 26/234 reads (11%) | called by muse, mutect2, varscan2
- MTX1 | c.42G>A p.T14= | Silent (SNP) | VAF 28/340 reads (8%) | called by muse, mutect2
- OR4F15 | c.627C>T p.G209= | Silent (SNP) | VAF 22/786 reads (3%) | called by muse, mutect2
- SENP3 | c.1263+76C>G | Intron (SNP) | VAF 7/144 reads (5%) | called by muse, mutect2
